EXCEPTIONAL_RESPONDERS case ER-ABS8 — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0ecc513e-8ced-4acd-928e-694d78a568b1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1941; Vital status: Alive.

Diagnoses (2)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Breast, NOS; Age at diagnosis: 62.1 years (22,675 days).
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Cecum; Site of resection or biopsy: Cecum; Classification of tumor: primary; Age at diagnosis: 70.4 years (25,719 days); Year of diagnosis: 2012; AJCC pathologic stage: Stage IVB; Prior malignancy: yes; Days to last follow up: 1,064 days (2.9 years); Days to best overall response: 346 days; Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Bevacizumab + Irinotecan; Days to treatment start: 292 days; Days to treatment end: 502 days (1.4 years).

Follow-up (1 entry)
- Days to follow up: 1,064 days (2.9 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 224 days; Days progression-free: 1,064 days (2.9 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABS8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-ABS8-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 54; Percent tumor nuclei: 15; Percent normal cells: 25; Percent necrosis: 21; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
